Somatic mutation profile of tumor specimen TCGA-06-0644-01A (aliquot TCGA-06-0644-01A-02D-1492-08) from TCGA case TCGA-06-0644, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.9 years (26,247 days).
Specimen TCGA-06-0644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efc254e5-8aa6-4e1c-9f97-9f8602e47709.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0644-10A (Blood Derived Normal), aliquot TCGA-06-0644-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba239c50-70bd-47fc-9390-fd41c803a5ca

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 18, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PTEN | c.607_608del p.I203Sfs*39 | Frame Shift Del (DEL) | VAF 87/238 reads (37%) | catalogued as rs1085308054; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4156G>A p.V1386I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as rs377479549; called by muse, mutect2, varscan2
- AMER3 | c.1298C>A p.P433H | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV58467018; called by muse, mutect2, varscan2
- B4GALNT3 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 34/126 reads (27%) | catalogued as rs780455486, COSV56752734; called by muse, mutect2, varscan2
- BPIFA3 | c.621+1G>T p.X207_splice | Splice Site (SNP) | VAF 30/110 reads (27%) | catalogued as COSV64925895; called by muse, mutect2, varscan2
- CCER1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.8); catalogued as COSV62646987; called by muse, mutect2, varscan2
- CDH7 | c.274A>G p.S92G | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.192); catalogued as COSV59886938; called by muse, mutect2, varscan2
- COL24A1 | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs538248306, COSV65301938; called by muse, mutect2, varscan2
- COL6A2 | c.1673C>T p.A558V | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs376303610; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CTBP2 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs748896311, COSV58334461; called by muse, mutect2, varscan2
- DRD5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256349931, COSV58577786; called by muse, mutect2, varscan2
- EIF2AK4 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 29/139 reads (21%) | catalogued as COSV55468764; called by muse, mutect2, varscan2
- FBN2 | c.1951C>G p.P651A | Missense Mutation (SNP) | VAF 57/213 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV52515582; called by muse, mutect2, varscan2
- GKN1 | c.392T>A p.L131Q | Missense Mutation (SNP) | VAF 51/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65006543; called by muse, mutect2, varscan2
- GRB10 | c.1673A>G p.D558G (on ENST00000398812; = p.D512G on NM_001001549.3) | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60010885; called by muse, mutect2, varscan2
- HHIPL1 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.559); catalogued as rs753488026, COSV58090787; called by muse, mutect2, varscan2
- KIT | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.458); catalogued as rs200950545, COSV55388186, COSV55389759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MDP1 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.182); catalogued as rs764385329, COSV51660431; called by muse, mutect2, varscan2
- MROH7 | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs367669775; called by muse, mutect2, varscan2
- MYOM1 | c.2363A>G p.N788S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV55292348; called by muse, mutect2, varscan2
- OLIG2 | c.362T>A p.M121K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60972663; called by muse, mutect2, varscan2
- OR1N2 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 104/354 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0.028); catalogued as rs777889887, COSV65460684; called by muse, mutect2, varscan2
- OTUD6A | c.343G>C p.A115P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV57973493; called by muse, mutect2, varscan2
- PCDHB11 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 75/239 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.384); catalogued as COSV61311842; called by muse, mutect2, varscan2
- PCLO | c.12398G>A p.R4133H | Missense Mutation (SNP) | VAF 47/245 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); catalogued as rs752661745, COSV61637369; called by muse, mutect2, varscan2
- PDE3A | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs1225099919, COSV62973728, COSV62974016; called by muse, mutect2, varscan2
- PIAS1 | c.1330G>T p.V444L | Missense Mutation (SNP) | VAF 54/191 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV51032274; called by muse, varscan2
- PRDM9 | c.1007A>T p.H336L | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV57006918; called by muse, varscan2
- PTPRT | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.979); catalogued as COSV61983557; called by muse, mutect2, varscan2
- RELN | c.9052C>T p.R3018* | Nonsense Mutation (SNP) | VAF 41/197 reads (21%) | catalogued as COSV59004300; called by muse, mutect2, varscan2
- REXO1 | c.3472G>A p.V1158M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50078672; called by muse, mutect2
- RIMS2 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372575949, COSV68481666; called by muse, mutect2, varscan2
- SLC46A2 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.845); catalogued as rs777014635, COSV65290049; called by muse, mutect2, varscan2
- SLC4A4 | c.1903+2T>C p.X635_splice (on ENST00000264485 / NM_001098484.3; = p.X591_splice on NM_003759.4) | Splice Site (SNP) | VAF 11/246 reads (4%) | catalogued as COSV52625110; called by muse, mutect2
- SUPT20H | c.694C>T p.R232C (on ENST00000350612 / NM_001014286.3; = p.R233C on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/404 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs569498102, COSV62248019; called by muse, varscan2
- TLR8 | c.2752G>A p.E918K (on ENST00000218032 / NM_138636.5; = p.E936K on NM_016610.4) | Missense Mutation (SNP) | VAF 70/130 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54318201, COSV54319409; called by muse, mutect2, varscan2
- WDR86 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752255098, COSV57840368; called by muse, mutect2, varscan2
- WNK2 | c.6751G>A p.G2251R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1049268598, COSV52943440; called by muse, mutect2, varscan2
- PCDH11Y | c.2114del p.F705Sfs*26 (on ENST00000400457 / NM_032973.2; = p.F694Sfs*26 on NM_032971.3) | Frame Shift Del (DEL) | VAF 83/172 reads (48%) | called by mutect2, pindel, varscan2
- PIM1 | c.91_93del p.K31del | In Frame Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- ABCB4 | c.300G>A p.L100= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV55935753; called by muse, mutect2, varscan2
- AC011455.2 | c.1359C>T p.G453= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as COSV55499804; called by muse, mutect2, varscan2
- AP002512.3 | c.537C>T p.N179= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as rs749194186, COSV54406835; called by muse, mutect2, varscan2
- BTBD11 | c.2523C>A p.L841= (on ENST00000280758 / NM_001018072.2; = p.L378= on NM_001017523.2) | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV55025015; called by muse, mutect2, varscan2
- CDH9 | c.564C>T p.D188= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as rs766465003, COSV50257070, COSV99148019; called by muse, mutect2, varscan2
- CDYL2 | c.483C>T p.A161= | Silent (SNP) | VAF 47/197 reads (24%) | catalogued as rs149557557; called by muse, mutect2, varscan2
- CENPF | c.4155C>T p.D1385= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs139914723; called by muse, mutect2, varscan2
- COL5A1 | c.999C>T p.V333= | Silent (SNP) | VAF 96/309 reads (31%) | catalogued as rs138702819; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDPGP1 | c.687C>T p.P229= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs1389698423, COSV61575818; called by muse, mutect2, varscan2
- LRIG1 | c.1209G>A p.S403= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as COSV56240556, COSV99834061; called by muse, mutect2, varscan2
- MXRA5 | c.6936C>T p.N2312= | Silent (SNP) | VAF 111/155 reads (72%) | catalogued as rs1395608870, COSV54227919; called by muse, mutect2, varscan2
- NUDT9 | c.447T>C p.N149= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV56196762; called by muse, mutect2
- PRSS16 | c.801G>A p.T267= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as COSV57915606; called by muse, mutect2, varscan2
- PTPRK | c.2559G>A p.G853= (on ENST00000368215 / NM_001291984.2; = p.G854= on NM_002844.4) | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs141454620, COSV63898782; called by muse, mutect2, varscan2
- RADX | c.201G>A p.V67= | Silent (SNP) | VAF 91/141 reads (65%) | catalogued as COSV65318738; called by muse, mutect2, varscan2
- RBP3 | c.1332C>T p.F444= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as rs200626545; called by muse, mutect2, varscan2
- SERPINA1 | c.681C>T p.T227= | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs766320203, COSV63345697; called by muse, mutect2, varscan2
- UBE4B | c.1953C>G p.G651= (on ENST00000343090 / NM_001105562.3; = p.G522= on NM_006048.5) | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV53533157, COSV53543169; called by muse, mutect2, varscan2
- GLRXP3 | n.201G>A | RNA (SNP) | VAF 70/243 reads (29%) | called by muse, mutect2, varscan2
